Somatic mutation profile of tumor specimen TCGA-24-1842-01A (aliquot TCGA-24-1842-01A-01W-0639-09) from TCGA case TCGA-24-1842, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 49.9 years (18,227 days).
Specimen TCGA-24-1842-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc8e736e-a2b4-4d81-a68c-5e35c0f648e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1842-10A (Blood Derived Normal), aliquot TCGA-24-1842-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18b233c9-15ff-44d8-94b0-f6ae2766bf2c

The open-access MAF lists 58 somatic variants for this specimen: 48 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 36, Silent 10, Frame Shift Del 4, Frame Shift Ins 3, Nonsense Mutation 2, Splice Site 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 24/35 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADD1 | c.2000C>A p.P667H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.085); catalogued as COSV53268614; called by muse, mutect2, varscan2
- ADGRE3 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.066); catalogued as rs377703147, COSV53732007; called by mutect2, varscan2
- ASXL3 | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as COSV52470533; called by muse, mutect2
- CADPS2 | c.2839G>A p.A947T | Missense Mutation (SNP) | VAF 126/190 reads (66%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs368742944, COSV57361048; called by muse, mutect2, varscan2
- CCDC54 | c.452C>T p.T151M | Missense Mutation (SNP) | VAF 207/508 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs753526671, COSV53758564, COSV99660345; called by muse, mutect2, varscan2
- CDK12 | c.2948_2950del p.R983_E984delinsQ | In Frame Del (DEL) | VAF 62/105 reads (59%) | catalogued as COSV71000448; called by mutect2, pindel, varscan2
- CDK16 | c.1028T>C p.I343T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52091915; called by muse, mutect2, varscan2
- CFAP47 | c.2255-1G>A p.X752_splice | Splice Site (SNP) | VAF 6/162 reads (4%) | catalogued as COSV99934758; called by muse, mutect2
- CLCN4 | c.955T>A p.F319I | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101073737; called by muse, mutect2
- CTNNAL1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100336446; called by muse, mutect2
- DARS1 | c.256A>C p.N86H | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV99927457; called by muse, mutect2
- DNM3 | c.367C>T p.R123* | Nonsense Mutation (SNP) | VAF 84/239 reads (35%) | catalogued as rs1171386565, COSV62457000; called by muse, mutect2, varscan2
- ENAM | c.2737G>A p.G913S | Missense Mutation (SNP) | VAF 80/810 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as rs762211625; called by muse, mutect2
- FBXL5 | c.1134G>A p.W378* | Nonsense Mutation (SNP) | VAF 70/91 reads (77%) | catalogued as rs1198022880, COSV58010669; called by muse, mutect2, varscan2
- GCN1 | c.7087dup p.V2363Gfs*18 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | catalogued as rs771010099; called by pindel, varscan2
- GLUD1 | c.1652A>G p.N551S | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs373705613; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGA4 | c.3942A>C p.E1314D | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as COSV62710447; called by muse, mutect2, varscan2
- GYS2 | c.1363C>G p.P455A | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.361); catalogued as rs1430038707, COSV53922755; called by muse, mutect2, varscan2
- HTR1D | c.995G>T p.W332L | Missense Mutation (SNP) | VAF 8/185 reads (4%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.701); catalogued as COSV100024781; called by muse, mutect2
- IFITM1 | c.89A>T p.E30V | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60249262; called by muse, mutect2, varscan2
- IQCG | c.766C>A p.Q256K | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV99502223; called by muse, mutect2
- KAT8 | c.288T>A p.F96L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV54896449; called by muse, varscan2
- KIF21A | c.1882G>A p.E628K (on ENST00000361418 / NM_001378440.1; = p.E615K on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV62770702; called by muse, mutect2
- KMT2C | c.13895-1G>C p.X4632_splice | Splice Site (SNP) | VAF 26/113 reads (23%) | catalogued as COSV51434194; called by muse, mutect2, varscan2
- KPRP | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.276); catalogued as COSV64221502; called by muse, mutect2, varscan2
- KRTAP15-1 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV61877101; called by muse, mutect2, varscan2
- MAPK7 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs775129236, COSV55189510; called by muse, mutect2, varscan2
- MRGPRD | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100482972; called by muse, mutect2
- NRK | c.2267A>G p.N756S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.968); catalogued as COSV54595281; called by muse, mutect2, varscan2
- OR2M3 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 249/647 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV71759013; called by muse, mutect2, varscan2
- PSG2 | c.983T>A p.L328H | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV61545132; called by muse, mutect2, varscan2
- SCN8A | c.5480T>C p.I1827T | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.165); catalogued as COSV100633595; called by muse, mutect2
- SLC27A6 | c.74del p.P25Lfs*11 | Frame Shift Del (DEL) | VAF 44/91 reads (48%) | catalogued as COSV99322496; called by mutect2, pindel, varscan2
- SLC38A2 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758389239, COSV56744863; called by muse, mutect2, varscan2
- SRP68 | c.601C>A p.H201N | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV57162455; called by muse, mutect2, varscan2
- TNR | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 91/318 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs774052903, COSV54873532; called by muse, mutect2, varscan2
- TRNT1 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV99214130; called by muse, mutect2
- TUBGCP6 | c.374T>C p.V125A | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV50542770; called by muse, mutect2, varscan2
- UMOD | c.840dup p.E281Rfs*18 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | catalogued as rs774365088; called by mutect2, pindel
- ZFHX3 | c.314dup p.P106Afs*13 | Frame Shift Ins (INS) | VAF 4/15 reads (27%) | catalogued as rs769936196; called by mutect2, varscan2
- ZNF236 | c.3334G>T p.V1112F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV99469847; called by muse, mutect2
- ZNF765 | c.486T>A p.N162K | Missense Mutation (SNP) | VAF 7/200 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV101125429, COSV101125463; called by muse, mutect2
- BSN | c.4766_4803del p.P1589Rfs*37 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- CCDC6 | c.1098_1104del p.I366Mfs*18 | Frame Shift Del (DEL) | VAF 16/97 reads (16%) | called by mutect2, pindel, varscan2
- IL21R | c.658_659del p.P220Gfs*54 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- MAP1LC3B | c.136G>T p.V46F | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.784); called by muse, mutect2
- TRERF1 | c.736C>A p.Q246K | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.696); called by muse, mutect2
- CLCN4 | c.954C>A p.L318= | Silent (SNP) | VAF 26/342 reads (8%) | catalogued as COSV101073736; called by muse, mutect2
- CLTCL1 | c.375C>T p.T125= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs782227482, COSV54229421; called by muse, mutect2, varscan2
- CSMD2 | c.6153C>A p.S2051= | Silent (SNP) | VAF 17/113 reads (15%) | catalogued as COSV53907069; called by muse, mutect2, varscan2
- JCAD | c.156G>A p.A52= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs376588282; called by muse, mutect2, varscan2
- MGA | c.4920C>T p.V1640= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs1335790839, COSV54952953; called by muse, mutect2, varscan2
- MTERF1 | c.609C>G p.T203= | Silent (SNP) | VAF 38/374 reads (10%) | catalogued as COSV61098173; called by muse, mutect2
- PDE8B | c.1947C>A p.L649= | Silent (SNP) | VAF 4/61 reads (7%) | called by muse, mutect2
- TAF1L | c.1254C>T p.D418= | Silent (SNP) | VAF 224/618 reads (36%) | catalogued as rs757349383, COSV54257434; called by muse, mutect2, varscan2
- ZNF275 | c.558C>T p.C186= | Silent (SNP) | VAF 40/164 reads (24%) | catalogued as rs782160473, COSV64704360; called by muse, mutect2, varscan2
- ZNF626 | c.780T>C p.D260= | Silent (SNP) | VAF 49/342 reads (14%) | catalogued as COSV74129407; called by muse, mutect2, varscan2
